TCGA case TCGA-BR-8361 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/86cbca52-29bd-4b88-a203-e8b9a072bd4b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.1; Tissue or organ of origin: Fundus of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 71.2 years (25,999 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 946 days (2.6 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 6; Lymph nodes tested: 10.

Follow-up (3 entries)
- Days to follow up: 12 days; Disease response: Tumor Free.
- Days to follow up: 593 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 946 days (2.6 years); Disease response: Tumor Free.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-8361-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 1.5; Shortest dimension: 0.5.
  Slide TCGA-BR-8361-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-BR-8361-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-BR-8361-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-8361-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Cancer procurement city: Tver.
- Follow-up form 1: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 946 days; disease-specific survival: no event (censored), 946 days; disease-free interval: no event (censored), 946 days; progression-free interval: no event (censored), 946 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-8361-01A-11D-2338-01): tumor purity 0.64, ploidy 2.01, whole-genome doublings 0.
